Somatic mutation profile of tumor specimen MMRF_1588_1_BM_CD138pos (aliquot MMRF_1588_1_BM_CD138pos_T1_KBS5U_L06417) from MMRF case MMRF_1588, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.5 years (24,657 days).
Specimen MMRF_1588_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa1e466a-b3ba-416d-ae92-ea05d5e8ad03.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1588_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1588_1_PB_Whole_C3_KBS5U_L06464; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff75b1ec-6127-4364-baff-c8a0161fb8b4

The open-access MAF lists 63 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 11, Silent 10, Intron 9, 5'UTR 4, 5'Flank 3, 3'Flank 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABO | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs369099974; called by muse, mutect2
- ANKRD30A | c.1648C>G p.P550A (on ENST00000611781; = p.P494A on NM_052997.2) | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as rs1307076678, COSV100653171, COSV64609766; called by muse, mutect2
- CSMD2 | c.8617C>T p.R2873C | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53960112; called by muse, mutect2, varscan2
- EGR1 | c.601C>G p.P201A | Missense Mutation (SNP) | VAF 10/338 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as COSV53518249; called by muse, mutect2
- GRM6 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs200306155, COSV51438936; called by muse, mutect2, varscan2
- IGHV2-70 | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs372640551; called by muse, varscan2
- IGKJ5 | c.10T>G p.F4V | Missense Mutation (SNP) | VAF 66/146 reads (45%) | catalogued as rs114105515; called by muse, varscan2
- IGKJ5 | c.4A>G p.I2V | Missense Mutation (SNP) | VAF 69/149 reads (46%) | catalogued as rs374322906; called by muse, varscan2
- IGLV3-1 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 41/98 reads (42%) | catalogued as rs376040566; called by muse, mutect2, varscan2
- LIG1 | c.1406T>C p.L469P | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1423467394; called by muse, mutect2, varscan2
- MAP3K9 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs887529850; called by muse, mutect2
- NAGA | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV101124170; called by muse, mutect2, varscan2
- PCDH1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54612344; called by muse, mutect2, varscan2
- RBM10 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61311387, COSV99051447; called by muse, mutect2
- SUZ12 | c.1316G>T p.R439M | Missense Mutation (SNP) | VAF 142/232 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV59503627; called by muse, mutect2, varscan2
- TMCC1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 75/290 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs766844460, COSV67875168; called by muse, mutect2, varscan2
- HAO2 | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV2-70D | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- IGHV2-70D | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, varscan2
- KIAA1586 | c.1718A>G p.K573R | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MRTFA | c.562A>G p.I188V | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RBBP6 | c.3598A>G p.I1200V | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- RP1L1 | c.6008C>T p.P2003L | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC6 | c.1724A>C p.Y575S | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.44); called by muse, mutect2
- GRN | c.237G>A p.G79= | Silent (SNP) | VAF 9/262 reads (3%) | called by muse, mutect2
- IGKV1-5 | c.306T>C p.P102= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs369716093; called by muse, varscan2
- IGKV1-5 | c.261T>C p.S87= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs11546107; called by muse, varscan2
- MRPL9 | c.552G>A p.L184= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV58617626; called by muse, mutect2, varscan2
- RGS7BP | c.15G>T p.P5= | Silent (SNP) | VAF 49/79 reads (62%) | catalogued as COSV61833788; called by muse, mutect2, varscan2
- TCOF1 | c.120G>A p.L40= | Silent (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- TRIM42 | c.984C>T p.D328= | Silent (SNP) | VAF 228/367 reads (62%) | catalogued as rs756059549, COSV53886422; called by muse, mutect2, varscan2
- TTN | c.18900T>A p.G6300= (on ENST00000591111; = p.G5373= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/218 reads (6%) | called by muse, mutect2
- UGT2B4 | c.714A>G p.E238= | Silent (SNP) | VAF 52/123 reads (42%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.396G>A p.T132= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs138630556; called by muse, mutect2, varscan2
- APEH | c.1210+42G>A | Intron (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2, varscan2
- ATRNL1 | c.*3537C>A | 3'UTR (SNP) | VAF 30/62 reads (48%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021276 T>A | 5'Flank (SNP) | VAF 38/84 reads (45%) | called by muse, varscan2
- BCL7A | chr12:122021359 T>C | 5'Flank (SNP) | VAF 26/65 reads (40%) | called by muse, varscan2
- C1orf131 | c.*96A>G | 3'UTR (SNP) | VAF 50/131 reads (38%) | called by muse, mutect2
- CDH10 | c.-13C>T | 5'UTR (SNP) | VAF 36/184 reads (20%) | catalogued as COSV52577049; called by muse, mutect2, varscan2
- CHCHD5 | c.2+242C>T | Intron (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- CLDN1 | c.224-58C>G | Intron (SNP) | VAF 42/73 reads (58%) | called by muse, mutect2, varscan2
- CLEC1B | c.439-228A>C | Intron (SNP) | VAF 7/15 reads (47%) | called by muse, varscan2
- DAW1 | c.*69C>A | 3'UTR (SNP) | VAF 104/223 reads (47%) | called by muse, mutect2, varscan2
- ERC1 | c.*1956C>A | 3'UTR (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- HTT | c.*3522C>G | 3'UTR (SNP) | VAF 23/64 reads (36%) | catalogued as rs972434893; called by muse, mutect2, varscan2
- JUN | c.*142G>C | 3'UTR (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- MKRN3 | c.-41C>T | 5'UTR (SNP) | VAF 4/50 reads (8%) | catalogued as rs1399917218; called by muse, mutect2
- MTO1 | chr6:73505987 T>G | 3'Flank (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- MUC4 | c.-59_-58del | 5'UTR (DEL) | VAF 24/79 reads (30%) | called by pindel, varscan2
- NAV3 | c.*1938G>T | 3'UTR (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- NLN | c.*5374G>A | 3'UTR (SNP) | VAF 26/75 reads (35%) | catalogued as rs901024734; called by muse, mutect2, varscan2
- NTRK2 | c.1397-52084G>A | Intron (SNP) | VAF 23/96 reads (24%) | catalogued as rs199824012; called by muse, mutect2, varscan2
- NUFIP2 | c.*147A>G | 3'UTR (SNP) | VAF 16/56 reads (29%) | called by muse, varscan2
- OPA3 | chr19:45584809 G>T | 5'Flank (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- RHEB | c.-205G>A | 5'UTR (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- SIGLEC1 | c.5071-200C>A | Intron (SNP) | VAF 20/39 reads (51%) | catalogued as COSV52474351; called by muse, mutect2, varscan2
- SLC2A5 | c.*1463_*1465del | 3'UTR (DEL) | VAF 19/131 reads (15%) | called by pindel, varscan2
- SLC6A14P2 | chrX:116692994 C>T | 3'Flank (SNP) | VAF 19/22 reads (86%) | catalogued as rs1270404883; called by muse, mutect2, varscan2
- ST3GAL5 | c.319-3547G>A | Intron (SNP) | VAF 73/206 reads (35%) | called by muse, mutect2, varscan2
- SYK | c.*2326G>A | 3'UTR (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- TP63 | c.325-18473A>G | Intron (SNP) | VAF 9/296 reads (3%) | catalogued as rs1223022500; called by muse, mutect2
- WAC | c.1288+440C>G | Intron (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
